MMRF case MMRF_1130 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9f08cfd6-ec10-41a0-aa8c-7e99a35e925a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.1 years (30,003 days); ISS stage: II; Days to last known disease status: 1,762 days (4.8 years); Days to last follow up: 1,762 days (4.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 351 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 361 days; Days to treatment end: 541 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 879 days (2.4 years); Days to treatment end: 1,243 days (3.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,373 days (3.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 659 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.288 mg/dL; Immunoglobulin G 47.1 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 4.9 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 9.3 g/dL; Glucose 4.73 mmol/L.
- Day 106 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.329 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 7.55 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 9.35 mmol/L.
- Day 155 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.617 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 8.32 ×10⁹/L; Absolute Neutrophil 7.85 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 8.03 mmol/L.
- Day 254 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.658 mg/dL; Immunoglobulin G 8.85 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 8.28 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 323 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.561 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 4.65 ×10⁹/L; Absolute Neutrophil 3.12 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 425 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.794 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 9.77 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 491 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.844 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 8.62 mmol/L; Leukocytes 5.95 ×10⁹/L; Absolute Neutrophil 4.08 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.68 mmol/L.
- Day 619 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 65.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 9.42 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 6.99 mmol/L.
- Day 705 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 115 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.688 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 9.18 mmol/L; Leukocytes 5.46 ×10⁹/L; Absolute Neutrophil 3.02 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.72 mmol/L.
- Day 792 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.359 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 940 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 98.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.733 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 6.11 mmol/L.
- Day 1,037 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 81.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.818 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.56 mmol/L.
- Day 1,134 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 63.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.793 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 3.84 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.89 mmol/L.
- Day 1,256: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.922 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 6.18 ×10⁹/L; Absolute Neutrophil 3.87 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.68 mmol/L.
- Day 1,355 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 219 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.686 mg/dL; Immunoglobulin G 21.8 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.6 µg/mL; Hemoglobin 9.42 mmol/L; Leukocytes 3.56 ×10⁹/L; Absolute Neutrophil 1.85 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 4.68 mmol/L.
- Day 1,443: M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 122 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 18.4 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.7 µg/mL; Hemoglobin 8.62 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 1,545: M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 86.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 3 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.9 mmol/L.
- Day 1,650 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 132 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 25.2 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 4.4 mmol/L.
- Day 1,762 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 91.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.809 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.6 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -10: Weight: 76 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1130_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1130_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
